Somatic mutation profile of tumor specimen C3L-03382-01 (aliquot CPT0240330006) from CPTAC case C3L-03382, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.6 years (26,136 days).
Specimen C3L-03382-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aa852e7-b08c-4f13-8613-33a39482517f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03382-31 (Blood Derived Normal), aliquot CPT0240640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d5605eb-c842-48d6-a20f-008efd01e04c

The open-access MAF lists 1,454 somatic variants for this specimen: 941 protein-altering or splice-affecting, 463 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 857, Silent 463, Nonsense Mutation 54, Intron 23, Splice Region 14, 3'UTR 13, Splice Site 9, 3'Flank 6, RNA 4, Frame Shift Ins 3, Frame Shift Del 3, 5'Flank 2.

Variants (750 of 1,454; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.4879C>T p.Q1627* | Nonsense Mutation (SNP) | VAF 103/268 reads (38%) | catalogued as rs886039592; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 253/321 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 251/317 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CDKN2A | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 233/350 reads (67%) | catalogued as rs121913383, COSV58683264, COSV58724303, COSV58727969; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CEP290 | c.1429C>T p.R477* | Nonsense Mutation (SNP) | VAF 56/172 reads (33%) | catalogued as rs1170451277, CM111855; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 142/357 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779693, CM000329; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 125/337 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as rs727504256, COSV51767260, COSV51795875; ClinVar: drug response; called by muse, mutect2, varscan2
- GAMT | c.491dup p.V165Rfs*26 | Frame Shift Ins (INS) | VAF 138/380 reads (36%) | catalogued as rs749390953; ClinVar: pathogenic; called by mutect2, varscan2
- HBB | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 115/289 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.099); catalogued as rs33969677, CD920866, CM077579, CM900317, CM930378; ClinVar: likely pathogenic / other / pathogenic; called by muse, mutect2, varscan2
- KIF1A | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 126/353 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131690804, COSV57486140; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3316C>T p.R1106* | Nonsense Mutation (SNP) | VAF 168/425 reads (40%) | catalogued as rs202033121, CM094636; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.6940G>A p.E2314K | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs794728748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2272C>T p.H758Y | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV104434308; called by muse, mutect2, varscan2
- ABCA13 | c.10204G>A p.G3402R | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143194909; called by muse, mutect2, varscan2
- ABCC8 | c.4545G>A p.T1515= | Splice Region (SNP) | VAF 101/289 reads (35%) | catalogued as rs372388771; called by muse, mutect2, varscan2
- ABCC9 | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 132/386 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs867812924, CM125529, COSV53974785; called by muse, mutect2, varscan2
- ABCG1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 150/371 reads (40%) | PolyPhen probably damaging (0.969); catalogued as COSV68252097; called by muse, mutect2, varscan2
- ABCG8 | c.1612G>A p.V538M | Missense Mutation (SNP) | VAF 233/655 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.331); catalogued as rs760447217; called by muse, mutect2, varscan2
- AC119396.1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 68/448 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV73928512; called by muse, varscan2
- ACAN | c.4354C>T p.P1452S | Missense Mutation (SNP) | VAF 146/520 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs1199278824, COSV100719335; called by muse, mutect2, varscan2
- ADARB2 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 78/519 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as rs372316430; called by muse, mutect2, varscan2
- ADCY8 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 139/539 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867747553, COSV53897387; called by muse, mutect2, varscan2
- ADGRL2 | c.2264C>T p.S755L (on ENST00000370717 / NM_001366005.1; = p.S742L on NM_012302.4) | Missense Mutation (SNP) | VAF 142/399 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV54657880; called by muse, mutect2, varscan2
- ADNP | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.303); catalogued as rs745897751; called by muse, mutect2, varscan2
- ADPRHL1 | c.5827C>T p.R1943C | Missense Mutation (SNP) | VAF 142/335 reads (42%) | SIFT tolerated, low confidence (0.22); catalogued as rs1346761048; called by muse, mutect2, varscan2
- AIRE | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 139/436 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV52396635; called by muse, mutect2, varscan2
- ALK | c.2730G>A p.M910I | Missense Mutation (SNP) | VAF 113/276 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs867621462, COSV66582907; called by muse, mutect2, varscan2
- ALPK3 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 177/518 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as rs756157290; called by muse, mutect2, varscan2
- AMBRA1 | c.1207C>T p.P403S (on ENST00000458649 / NM_001367468.1; = p.P313S on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/422 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as rs748267527, COSV54053936; called by muse, mutect2, varscan2
- AMER3 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 220/566 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs773964038; called by muse, mutect2, varscan2
- ANO4 | c.850C>T p.R284C (on ENST00000392977 / NM_001286615.2; = p.R249C on NM_178826.4) | Missense Mutation (SNP) | VAF 116/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs780598682, COSV54585802; called by muse, mutect2, varscan2
- APCS | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 137/325 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.078); catalogued as rs757884673; called by muse, mutect2, varscan2
- APOB | c.10991C>T p.S3664F | Missense Mutation (SNP) | VAF 145/405 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV99268191; called by muse, mutect2, varscan2
- ARAP1 | c.4153C>T p.R1385W (on ENST00000393609 / NM_001040118.2; = p.R1140W on NM_015242.4) | Missense Mutation (SNP) | VAF 138/332 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs762324064; called by muse, mutect2, varscan2
- ARFGEF1 | c.3814C>T p.R1272* | Nonsense Mutation (SNP) | VAF 116/452 reads (26%) | catalogued as COSV51607584; called by muse, mutect2, varscan2
- ARHGAP15 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 139/361 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV54493223; called by muse, mutect2, varscan2
- ARHGAP29 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 178/469 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs749168376; called by muse, mutect2, varscan2
- ARHGAP30 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 184/455 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63515435; called by muse, mutect2, varscan2
- ARHGAP32 | c.4597C>T p.R1533C (on ENST00000310343 / NM_001378025.1; = p.R1184C on NM_014715.4) | Missense Mutation (SNP) | VAF 145/404 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs142674734; called by muse, mutect2, varscan2
- ARID1B | c.3056G>A p.G1019D | Missense Mutation (SNP) | VAF 122/365 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1355816936; called by muse, mutect2, varscan2
- ARMC3 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs995739980; called by muse, mutect2, varscan2
- ASXL3 | c.5017C>T p.H1673Y | Missense Mutation (SNP) | VAF 154/406 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV99324517; called by muse, mutect2, varscan2
- ATP2B3 | c.1990G>A p.E664K | Missense Mutation (SNP) | VAF 230/295 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs782078554, COSV54847673; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 238/291 reads (82%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs752015489; called by muse, mutect2, varscan2
- ATP9A | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 78/229 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as rs1269052180, COSV100124566; called by muse, mutect2, varscan2
- BANK1 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 114/545 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1428281031, COSV59850255; called by muse, mutect2, varscan2
- BBS12 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 105/398 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV58561602; called by muse, mutect2, varscan2
- BCO2 | c.1030C>T p.L344F | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.937); catalogued as COSV99064408; called by muse, mutect2, varscan2
- BDP1 | c.2978C>T p.S993F | Missense Mutation (SNP) | VAF 209/543 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV62431962; called by muse, mutect2
- BHMT2 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104369908, COSV99670260; called by muse, varscan2
- BPIFA1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 101/254 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV62824268; called by muse, mutect2, varscan2
- BRINP1 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 158/422 reads (37%) | catalogued as COSV56291369; called by muse, mutect2, varscan2
- BUD23 | c.404C>T p.S135F | Missense Mutation (SNP) | VAF 136/330 reads (41%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.703); catalogued as rs145300786; called by muse, mutect2, varscan2
- C8orf37 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs377322234; called by muse, mutect2, varscan2
- CACNA1B | c.3727G>A p.D1243N | Missense Mutation (SNP) | VAF 43/207 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53120401; called by muse, mutect2, varscan2
- CACNA1H | c.6208C>T p.R2070C | Missense Mutation (SNP) | VAF 254/715 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as rs758461760, COSV52355028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM3 | c.166G>A p.E56K (on ENST00000368125 / NM_001127173.3; = p.E90K on NM_021189.5) | Missense Mutation (SNP) | VAF 143/387 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs372984577, COSV63684027; called by muse, mutect2, varscan2
- CAP1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.405); catalogued as rs746996102; called by muse, mutect2
- CAPN9 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 137/386 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55233384; called by muse, mutect2, varscan2
- CBLC | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 184/514 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs745556828, COSV54323156; called by muse, mutect2, varscan2
- CBLL2 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 192/252 reads (76%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs1043783362; called by muse, mutect2, varscan2
- CCDC102B | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 139/469 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as COSV100103120; called by muse, mutect2, varscan2
- CCDC105 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 167/409 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1377982947, COSV52963403; called by muse, mutect2, varscan2
- CCDC141 | c.2180G>A p.W727* | Nonsense Mutation (SNP) | VAF 108/273 reads (40%) | catalogued as rs1422829493, COSV55369906; called by muse, mutect2, varscan2
- CCDC168 | c.14324C>T p.A4775V | Missense Mutation (SNP) | VAF 117/338 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.731); catalogued as rs990738909; called by muse, mutect2, varscan2
- CCDC38 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 121/319 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1293079824; called by muse, mutect2, varscan2
- CCT8L2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 170/429 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as COSV63463437; called by muse, mutect2, varscan2
- CD163L1 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 84/290 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.447); catalogued as rs1408689949, COSV58014984; called by muse, mutect2, varscan2
- CD5L | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 155/419 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100941043; called by muse, mutect2, varscan2
- CD96 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 94/218 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51913310; called by muse, mutect2, varscan2
- CD96 | c.937G>A p.E313K (on ENST00000283285 / NM_198196.3; = p.E297K on NM_005816.5) | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV51914839; called by muse, mutect2, varscan2
- CDH11 | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 182/499 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1333609650, COSV51761650; called by muse, mutect2, varscan2
- CDH7 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 117/314 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs147015734; called by muse, mutect2, varscan2
- CDH9 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 133/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50250776, COSV50334530; called by muse, mutect2, varscan2
- CELF5 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 136/360 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53015139; called by muse, mutect2, varscan2
- CETP | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 150/371 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs745384723; called by muse, mutect2, varscan2
- CFAP47 | c.1858G>A p.D620N | Missense Mutation (SNP) | VAF 81/108 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52884651; called by muse, mutect2, varscan2
- CFAP52 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762206085; called by muse, mutect2, varscan2
- CFAP91 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 84/294 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56341867, COSV56345510; called by muse, mutect2, varscan2
- CFH | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66410340; called by muse, mutect2, varscan2
- CIITA | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 148/412 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs534970350; called by muse, mutect2, varscan2
- CLASP1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 66/195 reads (34%) | catalogued as COSV55313295; called by muse, mutect2, varscan2
- CLEC5A | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 461/554 reads (83%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.661); catalogued as rs140946328; called by muse, mutect2, varscan2
- CNR1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.647); catalogued as COSV62986979, COSV62990918; called by muse, mutect2, varscan2
- CNTN4 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 135/351 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.151); catalogued as rs759724901, COSV101281373, COSV68569064; called by muse, mutect2, varscan2
- CNTNAP2 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 149/188 reads (79%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.845); catalogued as rs956320440, COSV100674155, COSV62150880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTNAP5 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 154/422 reads (36%) | SIFT tolerated (0.64); PolyPhen probably damaging (1); catalogued as COSV101444152; called by muse, mutect2, varscan2
- COL11A2 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 260/1013 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs143571317; called by muse, mutect2, varscan2
- COL21A1 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 114/335 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs181443791; called by muse, mutect2, varscan2
- COL4A1 | c.3022G>A p.G1008R | Missense Mutation (SNP) | VAF 111/308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111423; called by muse, mutect2, varscan2
- COL4A3 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 112/345 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.959); catalogued as rs778166354, COSV67414472; called by muse, mutect2, varscan2
- COL4A3 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101170398; called by muse, mutect2, varscan2
- COL4A3 | c.2302G>A p.G768R | Missense Mutation (SNP) | VAF 125/380 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67418446; called by muse, mutect2, varscan2
- COLEC10 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 97/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867175886; called by muse, mutect2, varscan2
- CR1 | c.5464C>T p.R1822C | Missense Mutation (SNP) | VAF 152/461 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs191714506, COSV100887604; called by muse, mutect2, varscan2
- CSMD1 | c.8326C>T p.R2776* (on ENST00000520002; = p.R2775* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 162/459 reads (35%) | catalogued as rs368660845; called by muse, mutect2, varscan2
- CSMD3 | c.1373G>A p.G458E (on ENST00000297405 / NM_001363185.1; = p.G354E on NM_052900.3) | Missense Mutation (SNP) | VAF 100/386 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52142936, COSV52200982; called by muse, mutect2, varscan2
- CSNK2A1 | c.972C>T p.F324= | Splice Region (SNP) | VAF 100/330 reads (30%) | catalogued as rs1327760857, COSV99424488; called by muse, mutect2, varscan2
- CTAGE8 | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1352427140; called by muse, mutect2, varscan2
- CYP2W1 | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 128/329 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1224198810; called by muse, mutect2, varscan2
- CYP4A22 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 94/535 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.117); catalogued as rs1285432563, COSV53738598; called by muse, mutect2
- CYP8B1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 179/463 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as COSV60226997; called by muse, mutect2, varscan2
- DBH | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 208/521 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs373889996; called by muse, mutect2, varscan2
- DBX2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 128/351 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375287819, COSV60339154; called by muse, mutect2, varscan2
- DHX37 | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 135/392 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100438972; called by muse, mutect2, varscan2
- DIDO1 | c.3725C>T p.S1242F | Missense Mutation (SNP) | VAF 92/512 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs763831828; called by muse, mutect2, varscan2
- DIXDC1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 123/293 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782619996; called by muse, mutect2, varscan2
- DLGAP4 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 208/572 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs771828904; called by muse, mutect2, varscan2
- DMBT1 | c.3353C>T p.S1118F (on ENST00000338354 / NM_001377530.1; = p.S619F on NM_004406.3) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV100352462; called by mutect2, varscan2
- DMRTB1 | c.820C>T p.L274F | Missense Mutation (SNP) | VAF 268/687 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.198); catalogued as COSV65113135; called by muse, varscan2
- DNAH10 | c.8560C>T p.R2854C (on ENST00000409039; = p.R2793C on NM_207437.3) | Missense Mutation (SNP) | VAF 216/554 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759567865; called by muse, varscan2
- DNAH10 | c.12202G>A p.E4068K (on ENST00000409039; = p.E4007K on NM_207437.3) | Missense Mutation (SNP) | VAF 195/494 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV68990475; called by muse, mutect2, varscan2
- DNAH14 | c.8053G>A p.E2685K (on ENST00000445597; = p.E3488K on NM_001367479.1) | Missense Mutation (SNP) | VAF 263/345 reads (76%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs917132485, COSV59898014; called by muse, mutect2, varscan2
- DNAH14 | c.9071G>A p.S3024N (on ENST00000445597; = p.S3788N on NM_001367479.1) | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.062); catalogued as rs1468543353; called by muse, mutect2, varscan2
- DNAJB7 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1337471714; called by muse, mutect2, varscan2
- DPP10 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.444); catalogued as rs1559096058, COSV100065844, COSV59671071; called by muse, mutect2, varscan2
- DPPA4 | c.178+1G>A p.X60_splice | Splice Site (SNP) | VAF 113/259 reads (44%) | catalogued as rs776615241; called by muse, mutect2
- DPYD | c.2360G>A p.G787E | Missense Mutation (SNP) | VAF 206/462 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.317); catalogued as COSV100929216; called by muse, mutect2, varscan2
- DPYSL5 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 163/420 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56512998; called by muse, mutect2, varscan2
- DSCAM | c.4937C>T p.S1646L | Missense Mutation (SNP) | VAF 48/292 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV101261384; called by muse, mutect2, varscan2
- DSCAM | c.1970C>T p.S657F | Missense Mutation (SNP) | VAF 185/469 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV68024013; called by muse, mutect2, varscan2
- DSG4 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 182/407 reads (45%) | catalogued as rs1021447849, COSV100355974; called by muse, mutect2, varscan2
- DSTYK | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 126/340 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs868788895, COSV65688701; called by muse, mutect2, varscan2
- EDNRA | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 52/315 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.657); catalogued as rs771470596, COSV60098975; called by muse, mutect2, varscan2
- ENPP3 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 105/302 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716769, COSV62956659; called by muse, mutect2, varscan2
- ENTPD1 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 118/303 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as rs1202376698, COSV64602850; called by muse, mutect2, varscan2
- ERAP2 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.279); catalogued as COSV65938855; called by muse, mutect2, varscan2
- ERBB4 | c.2966G>A p.G989D | Missense Mutation (SNP) | VAF 41/201 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs757867095; called by muse, mutect2, varscan2
- ERICH3 | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 119/368 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs779101589, COSV58605623; called by muse, mutect2, varscan2
- ERICH3 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 175/447 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58608388; called by muse, mutect2, varscan2
- ESRP2 | c.1165G>A p.E389K (on ENST00000565858 / NM_001365264.1; = p.E379K on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 250/604 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as rs540156390, COSV52176107; called by muse, mutect2, varscan2
- ESRRA | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 207/517 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs1299366203; called by muse, mutect2, varscan2
- ESRRB | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 116/311 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs375828536; called by muse, mutect2, varscan2
- ESYT1 | c.593T>C p.V198A | Missense Mutation (SNP) | VAF 125/340 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.026); catalogued as COSV57275261; called by muse, mutect2, varscan2
- FABP6 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 110/250 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs1372547844; called by muse, mutect2, varscan2
- FAM163A | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 210/626 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.668); catalogued as rs1389184987; called by muse, mutect2, varscan2
- FAM186A | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 166/489 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.32); catalogued as rs1192961500, COSV59249114; called by muse, mutect2, varscan2
- FAM83B | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 173/566 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as COSV60925207, COSV60925693; called by muse, mutect2, varscan2
- FAM98A | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs766804546; called by muse, mutect2, varscan2
- FANCM | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as COSV99951485; called by muse, mutect2, varscan2
- FAT3 | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 87/248 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as COSV53163808; called by muse, mutect2, varscan2
- FAT3 | c.2531C>T p.S844L | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as COSV53081548; called by muse, mutect2, varscan2
- FAT3 | c.3223G>A p.D1075N | Missense Mutation (SNP) | VAF 107/324 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV53162980; called by muse, mutect2, varscan2
- FBLN7 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1330891856; called by muse, mutect2, varscan2
- FCGRT | c.917G>A p.G306D | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1459473819, COSV54543846; called by muse, mutect2, varscan2
- FER1L6 | c.4675G>A p.D1559N | Missense Mutation (SNP) | VAF 280/471 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1320527028, COSV67549426, COSV67553197; called by muse, mutect2, varscan2
- FGB | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 133/497 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as COSV57417559, COSV57419439; called by muse, mutect2, varscan2
- FGF10 | c.578G>A p.R193Q | Missense Mutation (SNP) | VAF 104/279 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.319); catalogued as rs1158466327, COSV52932133, COSV52939185; called by muse, mutect2, varscan2
- FGF14 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 101/263 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs771857870, COSV65960300; called by muse, mutect2, varscan2
- FGF3 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 122/347 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61926788; called by muse, mutect2, varscan2
- FGF6 | c.434G>A p.G145E | Missense Mutation (SNP) | VAF 88/244 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57404128; called by muse, mutect2, varscan2
- FIGN | c.799dup p.A267Gfs*100 | Frame Shift Ins (INS) | VAF 150/398 reads (38%) | catalogued as rs755527396; called by mutect2, varscan2
- FLT1 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 106/275 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as COSV56727195; called by muse, mutect2, varscan2
- FMN2 | c.3938T>C p.L1313P | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as COSV60421040; called by muse, mutect2, varscan2
- FMR1NB | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 87/130 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1034123999, COSV65071138; called by muse, mutect2, varscan2
- FOXD2 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 218/555 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.312); catalogued as rs761148740, COSV58304326; called by muse, mutect2, varscan2
- FREM2 | c.7243G>A p.D2415N | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as rs563216892, COSV54832421, COSV54837001; called by muse, mutect2, varscan2
- FRMPD3 | c.4516G>A p.E1506K | Missense Mutation (SNP) | VAF 242/312 reads (78%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as rs967128990; called by muse, mutect2, varscan2
- FSHR | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV58619534; called by muse, mutect2, varscan2
- FSIP2 | c.12766G>A p.E4256K | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs963551196, COSV104420951; called by muse, mutect2, varscan2
- GABRG1 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 155/353 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.142); catalogued as rs79036998; called by muse, mutect2, varscan2
- GALM | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 101/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747997001; called by muse, mutect2, varscan2
- GAS2L2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 211/577 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.039); catalogued as rs141214936; called by muse, mutect2, varscan2
- GHR | c.1819C>T p.L607F | Missense Mutation (SNP) | VAF 149/408 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100051718; called by muse, mutect2, varscan2
- GJA8 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 198/494 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); catalogued as rs782817804, COSV53787786; ClinVar: likely benign; called by muse, mutect2, varscan2
- GMEB1 | c.215C>T p.T72M | Missense Mutation (SNP) | VAF 129/332 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1398745872; called by muse, mutect2, varscan2
- GPALPP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 154/425 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1269071808; called by muse, mutect2, varscan2
- GPR1 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 204/468 reads (44%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.961); catalogued as rs1467692061; called by muse, mutect2, varscan2
- GPRC6A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 126/369 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369734914, COSV59953059; called by muse, mutect2, varscan2
- GRIK1 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053395983, COSV58718191; called by muse, varscan2
- GRIN2B | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 169/374 reads (45%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.917); catalogued as rs1295510907, COSV74204691; called by muse, mutect2, varscan2
- HCFC1 | c.2588C>T p.S863F | Missense Mutation (SNP) | VAF 251/321 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV60069835; called by muse, mutect2, varscan2
- HCFC1 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 252/338 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV60076634; called by muse, mutect2, varscan2
- HCLS1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 94/255 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759812697; called by muse, mutect2, varscan2
- HCN1 | c.1517G>A p.G506E | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57503052; called by muse, mutect2, varscan2
- HELZ | c.3749C>T p.P1250L | Missense Mutation (SNP) | VAF 81/473 reads (17%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.057); catalogued as COSV62378558; called by muse, mutect2, varscan2
- HHIP | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 101/418 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99667623; called by muse, mutect2, varscan2
- HHIP | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 86/329 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.434); catalogued as rs1453849578; called by muse, mutect2, varscan2
- HID1 | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 87/563 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV60912720; called by muse, mutect2, varscan2
- HIVEP2 | c.3290T>C p.V1097A | Missense Mutation (SNP) | VAF 177/501 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs769505698; called by muse, mutect2, varscan2
- HMCN1 | c.16619C>T p.S5540F | Missense Mutation (SNP) | VAF 175/425 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV54886414; called by muse, mutect2, varscan2
- HS6ST3 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 194/496 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65002174; called by muse, mutect2, varscan2
- HSD3B1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.541); catalogued as rs369792933; called by muse, mutect2, varscan2
- HSPBP1 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 140/379 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as rs565167097; called by muse, mutect2, varscan2
- HTR3D | c.784C>T p.P262S (on ENST00000382489 / NM_001163646.2; = p.P89S on NM_182537.3) | Missense Mutation (SNP) | VAF 175/483 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV61915526; called by muse, mutect2, varscan2
- HYDIN | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs113898693, COSV55479229; called by muse, mutect2, varscan2
- IFT88 | c.908C>T p.S303L (on ENST00000319980 / NM_001318493.2; = p.S294L on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.578); catalogued as rs770183666; called by muse, mutect2, varscan2
- IGHV1-46 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 69/205 reads (34%) | catalogued as rs1246309526; called by muse, mutect2, varscan2
- IGHV3-21 | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 147/598 reads (25%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.108); catalogued as rs563652068; called by muse, mutect2, varscan2
- IGKJ4 | c.5C>T p.T2I | Missense Mutation (SNP) | VAF 159/415 reads (38%) | PolyPhen probably damaging (0.958); catalogued as rs187905157; called by muse, mutect2, varscan2
- IL2 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202027273; called by muse, mutect2, varscan2
- IL20RB | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as rs1225113126; called by muse, mutect2, varscan2
- ILDR1 | c.1267G>A p.D423N (on ENST00000344209 / NM_001199799.2; = p.D379N on NM_175924.4) | Missense Mutation (SNP) | VAF 170/455 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as rs1172585670, COSV56553190; ClinVar: uncertain significance; called by muse, varscan2
- ING3 | c.550A>T p.T184S | Missense Mutation (SNP) | VAF 204/253 reads (81%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs200902834; called by muse, mutect2, varscan2
- INHBA | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.971); catalogued as COSV54226799; called by muse, mutect2, varscan2
- INPP4B | c.2512C>T p.R838C | Missense Mutation (SNP) | VAF 188/334 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1451831325, COSV53711475; called by muse, mutect2, varscan2
- INPP5B | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 165/422 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as rs1376288546; called by muse, mutect2, varscan2
- IPO11 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs140147182, COSV57581078; called by muse, mutect2, varscan2
- IQGAP2 | c.4214G>A p.R1405Q | Missense Mutation (SNP) | VAF 71/173 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs189501812, COSV57182293; called by muse, mutect2, varscan2
- ITGA7 | c.2137G>A p.D713N (on ENST00000555728; = p.D669N on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 113/286 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.045); catalogued as rs1490372035, COSV57695496; called by muse, mutect2
- ITIH5 | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56900108; called by muse, mutect2, varscan2
- JARID2 | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 175/792 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1178362050; called by muse, mutect2, varscan2
- JPH3 | c.953A>G p.N318S | Missense Mutation (SNP) | VAF 215/565 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762639695; called by muse, mutect2, varscan2
- KCNA5 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 217/650 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs941518325; called by muse, mutect2, varscan2
- KCNH5 | c.1778G>A p.G593E | Missense Mutation (SNP) | VAF 148/377 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100527795, COSV59768158; called by muse, mutect2, varscan2
- KCNH7 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 160/436 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59812734; called by muse, mutect2, varscan2
- KCNK1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 199/487 reads (41%) | catalogued as COSV64035642; called by muse, mutect2, varscan2
- KCNQ5 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 80/186 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59654975; called by muse, varscan2
- KCNT1 | c.2792G>A p.R931Q (on ENST00000488444; = p.R950Q on NM_020822.3) | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs886043455, CM159167; ClinVar: conflicting interpretations of pathogenicity / pathogenic; called by muse, mutect2, varscan2
- KCNV1 | c.387C>G p.C129W | Missense Mutation (SNP) | VAF 163/623 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52086543; called by muse, mutect2, varscan2
- KDM5C | c.3037C>T p.P1013S | Missense Mutation (SNP) | VAF 208/266 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100949348; called by muse, mutect2, varscan2
- KDM5C | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 115/164 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV64763708, COSV64765815; called by muse, mutect2, varscan2
- KHDRBS2 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as rs151269502, COSV55437595; called by muse, mutect2, varscan2
- KIAA1549 | c.5564C>T p.S1855L | Missense Mutation (SNP) | VAF 152/561 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1467100522, COSV54305592; called by muse, varscan2
- KIF12 | c.1212G>A p.M404I (on ENST00000640217; = p.M266I on NM_138424.1) | Missense Mutation (SNP) | VAF 122/340 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1187711117; called by muse, mutect2, varscan2
- KIF2B | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 139/385 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as rs753998197, COSV52135681; called by muse, mutect2, varscan2
- KNDC1 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 249/661 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs1230130058; called by muse, mutect2, varscan2
- KPNA4 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1427724913, COSV62075244; called by muse, mutect2, varscan2
- KRTAP1-5 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 233/645 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs528921363; called by muse, mutect2, varscan2
- KRTAP10-11 | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 288/781 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as rs782600775; called by muse, mutect2, varscan2
- LAMA1 | c.7181G>A p.R2394Q | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140792199; called by muse, mutect2, varscan2
- LAMA1 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 104/270 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1401583893, COSV67540886; called by muse, mutect2, varscan2
- LEPR | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 149/382 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.043); catalogued as rs1320530136, COSV60747550; called by muse, mutect2, varscan2
- LGI2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.104); catalogued as rs1275000496; called by muse, mutect2, varscan2
- LILRA5 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 120/338 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV56644993; called by muse, mutect2, varscan2
- LILRB5 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 235/638 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV60260457; called by mutect2, varscan2
- LRP1B | c.13507G>A p.D4503N | Missense Mutation (SNP) | VAF 131/379 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV67239110; called by muse, mutect2, varscan2
- LRP8 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 244/687 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1364119120, COSV100036263; called by muse, mutect2, varscan2
- LRRC42 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 118/342 reads (35%) | catalogued as rs41302780, COSV59961426; called by muse, mutect2, varscan2
- LRRC4B | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 72/482 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775403394, COSV65350773; called by muse, mutect2, varscan2
- LRRC4C | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 108/449 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs865871663, COSV53419875, COSV53425921; called by muse, mutect2, varscan2
- LTBP2 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1466624298, COSV56207435; called by muse, mutect2, varscan2
- MAGEC1 | c.2173C>T p.H725Y | Missense Mutation (SNP) | VAF 210/267 reads (79%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs768279920; called by muse, mutect2, varscan2
- MAGI2 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 90/233 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.018); catalogued as rs138307945; called by muse, mutect2, varscan2
- MAPT | c.1379G>A p.G460E (on ENST00000262410 / NM_001377265.1; = p.G134E on NM_005910.5) | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as COSV99291546; called by muse, mutect2, varscan2
- MARS2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 175/461 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs748332401; called by muse, mutect2, varscan2
- MAST4 | c.1408C>T p.R470* (on ENST00000403625 / NM_001164664.2; = p.R281* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 101/272 reads (37%) | catalogued as COSV55121118; called by muse, mutect2, varscan2
- MBD1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 147/383 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867327108; called by muse, mutect2, varscan2
- MCM10 | c.2245G>A p.E749K (on ENST00000484800 / NM_182751.3; = p.E748K on NM_018518.5) | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs201520041; called by muse, mutect2, varscan2
- MCTP1 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as rs868152630; called by muse, mutect2, varscan2
- MECOM | c.1832G>A p.G611E (on ENST00000468789 / NM_001105078.4; = p.G799E on NM_004991.4) | Missense Mutation (SNP) | VAF 154/433 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267599684, COSV52962370; called by muse, mutect2, varscan2
- MEGF6 | c.3832C>T p.L1278F | Missense Mutation (SNP) | VAF 213/520 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.039); catalogued as COSV99620084; called by muse, mutect2, varscan2
- MERTK | c.1605G>A p.G535= | Splice Region (SNP) | VAF 83/225 reads (37%) | catalogued as COSV99774041; called by muse, mutect2, varscan2
- MERTK | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 90/235 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.023); catalogued as rs752793588, COSV54935268; called by muse, mutect2, varscan2
- MFSD6 | c.2173-1G>A p.X725_splice | Splice Site (SNP) | VAF 99/210 reads (47%) | catalogued as rs780857461, COSV99855287; called by muse, mutect2, varscan2
- MGAM2 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 272/340 reads (80%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs1251144551; called by muse, mutect2, varscan2
- MGLL | c.58C>T p.P20S (on ENST00000398104 / NM_001003794.2; = p.P30S on NM_007283.6) | Missense Mutation (SNP) | VAF 181/524 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs373555899; called by muse, mutect2, varscan2
- MORN3 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 121/400 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV62507290; called by muse, mutect2, varscan2
- MROH9 | c.859C>T p.H287Y | Missense Mutation (SNP) | VAF 109/280 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV63010437; called by muse, mutect2, varscan2
- MTTP | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 115/560 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as rs1486107465; called by muse, mutect2, varscan2
- MUC16 | c.26542G>A p.E8848K | Missense Mutation (SNP) | VAF 163/436 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as rs758682809, COSV67446748, COSV67446844; called by muse, mutect2, varscan2
- MUC16 | c.15740C>T p.T5247I | Missense Mutation (SNP) | VAF 154/399 reads (39%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.009); catalogued as COSV67468475; called by muse, mutect2, varscan2
- MUC16 | c.9637G>A p.E3213K | Missense Mutation (SNP) | VAF 104/301 reads (35%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs865897685, COSV101197664, COSV67467593; called by muse, mutect2, varscan2
- MUC17 | c.9131G>A p.G3044E | Missense Mutation (SNP) | VAF 122/362 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); catalogued as COSV60297764; called by muse, mutect2, varscan2
- MUC19 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT tolerated (0.48); PolyPhen probably damaging (1); catalogued as rs1473474052; called by muse, varscan2
- MUC2 | c.2672C>T p.S891L | Missense Mutation (SNP) | VAF 167/429 reads (39%) | SIFT tolerated (0.09); catalogued as rs770253933; called by muse, mutect2, varscan2
- MUC20 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 257/1122 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs533915346, COSV57848880; called by muse, mutect2
- MX2 | c.1429C>T p.H477Y | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0.021); catalogued as rs1349000362; called by muse, mutect2, varscan2
- MYBPC1 | c.1864C>T p.P622S (on ENST00000550270 / NM_206820.2; = p.P647S on NM_002465.4) | Missense Mutation (SNP) | VAF 49/284 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62258059; called by muse, mutect2, varscan2
- MYH15 | c.4762C>T p.L1588F | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1025284099; called by muse, mutect2, varscan2
- MYH2 | c.1651T>C p.F551L | Missense Mutation (SNP) | VAF 188/467 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as rs1439972247; called by muse, mutect2, varscan2
- MYH4 | c.3568G>A p.E1190K | Missense Mutation (SNP) | VAF 176/451 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs766733986, COSV55118667; called by muse, mutect2, varscan2
- MYO16 | c.3230G>A p.G1077E | Missense Mutation (SNP) | VAF 128/380 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1217816112, COSV62744893; called by muse, mutect2, varscan2
- NAP1L2 | c.1378C>T p.R460C | Missense Mutation (SNP) | VAF 74/98 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV65172347; called by muse, mutect2, varscan2
- NBEA | c.7171C>T p.R2391* | Nonsense Mutation (SNP) | VAF 71/148 reads (48%) | catalogued as COSV59829064; called by muse, mutect2, varscan2
- NCOR2 | c.3524G>A p.R1175Q | Missense Mutation (SNP) | VAF 186/478 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs748921061; called by muse, mutect2, varscan2
- NEFM | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 191/450 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as rs757795369, COSV99647002; called by muse, mutect2, varscan2
- NEXMIF | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 179/241 reads (74%) | SIFT tolerated (0.23); PolyPhen benign (0.163); catalogued as rs868209183, COSV50062443; called by muse, mutect2, varscan2
- NEXMIF | c.3460C>T p.P1154S | Missense Mutation (SNP) | VAF 181/233 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.776); catalogued as rs781129973; called by muse, mutect2, varscan2
- NFE2L2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 148/417 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs368680070; called by muse, mutect2, varscan2
- NLGN4X | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 190/255 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766889075, COSV52026313, COSV99322183; called by muse, mutect2, varscan2
- NLRP2 | c.464-1G>A p.X155_splice | Splice Site (SNP) | VAF 103/277 reads (37%) | catalogued as COSV54756616; called by muse, mutect2, varscan2
- NODAL | c.779G>A p.G260E | Missense Mutation (SNP) | VAF 153/409 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99755617; called by muse, mutect2, varscan2
- NOL9 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66625802; called by muse, mutect2, varscan2
- NPFFR2 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 77/310 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.617); catalogued as rs779093966; called by muse, mutect2, varscan2
- NPY5R | c.1040T>C p.V347A | Missense Mutation (SNP) | VAF 95/394 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1424004129; called by muse, mutect2, varscan2
- NTN4 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 179/457 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as rs145923524; called by muse, mutect2, varscan2
- NTRK2 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs1408094711, COSV52867840; called by muse, mutect2, varscan2
- NUGGC | c.43G>A p.V15I | Missense Mutation (SNP) | VAF 97/274 reads (35%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.037); catalogued as COSV58435956; called by muse, mutect2, varscan2
- NUP214 | c.3265C>T p.P1089S | Missense Mutation (SNP) | VAF 18/463 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV63911906; called by muse, mutect2
- NXPE4 | c.1513G>A p.D505N (on ENST00000375478 / NM_001077639.2; = p.D221N on NM_017678.3) | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV64944483; called by muse, mutect2, varscan2
- NYAP2 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 121/304 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56000773; called by muse, mutect2, varscan2
- NYAP2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 188/433 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs373618687; called by muse, mutect2, varscan2
- OASL | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 139/440 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); catalogued as COSV99042909; called by muse, mutect2, varscan2
- OCA2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 137/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100667361, COSV100668489; called by muse, mutect2, varscan2
- OGDHL | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 161/408 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763967997, COSV65101511; called by muse, mutect2, varscan2
- OLAH | c.736G>A p.E246K (on ENST00000378228 / NM_001039702.3; = p.E299K on NM_018324.3) | Missense Mutation (SNP) | VAF 145/394 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); catalogued as rs1343008369, COSV62252277; called by muse, mutect2, varscan2
- OOSP4A | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.96); catalogued as rs1261189050; called by muse, mutect2, varscan2
- OR10A6 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 143/438 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV59164741; called by muse, mutect2, varscan2
- OR10AG1 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 135/410 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs548174450, COSV56632166; called by muse, mutect2, varscan2
- OR13C3 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 168/456 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV66165854; called by muse, mutect2
- OR2J3 | c.609G>A p.M203I | Missense Mutation (SNP) | VAF 191/609 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1458090557, COSV65849602; called by muse, mutect2, varscan2
- OR2M2 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs200277557; called by muse, mutect2, varscan2
- OR4A5 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 156/414 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV60524976; called by muse, mutect2, varscan2
- OR4E2 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 148/376 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as rs370388172, COSV57731422; called by muse, mutect2, varscan2
- OR4X2 | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 186/473 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs867336590; called by muse, mutect2, varscan2
- OR51F2 | c.138G>A p.M46I | Missense Mutation (SNP) | VAF 168/394 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.027); catalogued as COSV59063803; called by muse, mutect2, varscan2
- OR51G2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 135/364 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs201238790; called by muse, mutect2, varscan2
- OR5L2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 120/361 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65724647; called by muse, mutect2, varscan2
- OR5R1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 166/494 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56573433; called by muse, mutect2
- OR5R1 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 124/317 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56572951; called by muse, mutect2, varscan2
- OR6T1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 151/415 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770876608, COSV58305477; called by muse, mutect2, varscan2
- OR8S1 | c.130A>C p.M44L | Missense Mutation (SNP) | VAF 115/369 reads (31%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV59600034; called by muse, mutect2, varscan2
- OSMR | c.1786C>T p.R596* | Nonsense Mutation (SNP) | VAF 91/250 reads (36%) | catalogued as rs199844167; called by muse, mutect2, varscan2
- OTX2 | c.608C>T p.S203L (on ENST00000408990 / NM_172337.3; = p.S211L on NM_021728.4) | Missense Mutation (SNP) | VAF 176/497 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV59767727; called by muse, mutect2, varscan2
- OVCH1 | c.3040C>T p.P1014S | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1461520282; called by muse, mutect2
- OVCH2 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV101491902; called by muse, mutect2, varscan2
- PCARE | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 168/500 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.146); catalogued as COSV100527936, COSV59058310; called by muse, mutect2, varscan2
- PCDHA1 | c.1384G>A p.V462I | Missense Mutation (SNP) | VAF 252/658 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.857); catalogued as COSV65374174; called by muse, varscan2
- PCDHB13 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 90/316 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99507559; called by muse, mutect2, varscan2
- PCDHB14 | c.1049C>T p.S350L | Missense Mutation (SNP) | VAF 148/379 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.631); catalogued as rs782128160, COSV53387585; called by muse, mutect2, varscan2
- PCDHGB6 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 125/391 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.26); catalogued as rs1304936825; called by muse, mutect2, varscan2
- PCLO | c.8545G>A p.E2849K | Missense Mutation (SNP) | VAF 118/332 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as rs1011437075, COSV61668909; called by muse, mutect2, varscan2
- PDE1A | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100114242, COSV59518500; called by muse, mutect2, varscan2
- PDE1C | c.2088G>A p.M696I | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV58514543; called by muse, mutect2, varscan2
- PDYN | c.530G>C p.G177A | Missense Mutation (SNP) | VAF 148/444 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54100841; called by muse, mutect2, varscan2
- PEBP4 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56464831; called by muse, mutect2, varscan2
- PER1 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 154/441 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs937895139, COSV57921304; called by muse, mutect2, varscan2
- PHF20L1 | c.1847C>T p.T616M | Missense Mutation (SNP) | VAF 67/529 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs375139491; called by muse, mutect2, varscan2
- PHYH | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 157/401 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934688734; called by muse, mutect2, varscan2
- PIK3C2G | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 118/329 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.124); catalogued as COSV56841243; called by muse, mutect2, varscan2
- PIK3IP1 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 315/409 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99314002; called by muse, mutect2, varscan2
- PKN3 | c.1199C>T p.S400F | Missense Mutation (SNP) | VAF 127/414 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.424); catalogued as rs1324318558; called by muse, mutect2, varscan2
- PLAAT1 | c.463C>T p.P155S (on ENST00000650797; = p.P50S on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.155); catalogued as rs1451756569; called by muse, mutect2, varscan2
- PLEKHG2 | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 216/505 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52683748; called by muse, mutect2, varscan2
- POLI | c.1702G>A p.V568I | Missense Mutation (SNP) | VAF 107/291 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs762173259; called by muse, mutect2, varscan2
- POLRMT | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 215/491 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as rs940113761; called by muse, mutect2, varscan2
- POTEF | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 56/420 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.965); catalogued as rs765558619; called by muse, mutect2, varscan2
- POTEI | c.2830G>A p.D944N | Missense Mutation (SNP) | VAF 31/173 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.999); catalogued as rs760161629; called by muse, mutect2, varscan2
- POTEI | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 148/608 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as COSV71576361; called by muse, mutect2, varscan2
- PPP1R42 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61208691; called by muse, mutect2, varscan2
- PPP2R2B | c.556G>A p.E186K (on ENST00000394409; = p.E252K on NM_181674.2) | Missense Mutation (SNP) | VAF 144/426 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV60765231; called by muse, mutect2, varscan2
- PPP3R2 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 144/434 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62458770; called by muse, mutect2, varscan2
- PPP4R3C | c.1306C>T p.H436Y | Missense Mutation (SNP) | VAF 108/139 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1333226953; called by muse, mutect2, varscan2
- PRDM16 | c.3733C>T p.P1245S | Missense Mutation (SNP) | VAF 133/380 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs761238816, COSV54583365; called by muse, mutect2, varscan2
- PRDM9 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 132/370 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57002771, COSV57005738; called by muse, mutect2, varscan2
- PRPF39 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53533124; called by muse, mutect2, varscan2
- PRRC2C | c.6785C>T p.S2262F (on ENST00000367742; = p.S2260F on NM_015172.4) | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58903134, COSV58903621; called by muse, mutect2, varscan2
- PRSS22 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 133/427 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs911270196; called by muse, mutect2, varscan2
- PRSS35 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 173/431 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267601142, COSV63800463; called by muse, mutect2, varscan2
- PTCH1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 114/347 reads (33%) | catalogued as CM113233, COSV59481726; called by muse, mutect2, varscan2
- PTPN5 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 209/479 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs765053589; called by muse, mutect2, varscan2
- PTPRQ | c.1916G>A p.G639E (on ENST00000616559; = p.G597E on NM_001145026.2) | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57044347; called by muse, mutect2, varscan2
- PWWP3B | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 209/254 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100531607; called by muse, mutect2, varscan2
- PXDNL | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 298/564 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1308067576, COSV100685287; called by muse, mutect2, varscan2
- RAB6B | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 164/411 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV53313024; called by muse, mutect2, varscan2
- RAI1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 225/526 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1424544991, COSV99883013; called by muse, mutect2, varscan2
- RAP1GAP2 | c.2066G>A p.G689E | Missense Mutation (SNP) | VAF 128/353 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs1273713650; called by muse, mutect2, varscan2
- RCHY1 | c.350dup p.H118Pfs*6 | Frame Shift Ins (INS) | VAF 78/312 reads (25%) | catalogued as rs760060750; called by mutect2, pindel, varscan2
- RESP18 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.984); catalogued as COSV61113657; called by muse, mutect2, varscan2
- RETNLB | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV55466445; called by muse, mutect2, varscan2
- RGS7 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755007339, COSV58530073, COSV58530443; called by muse, mutect2, varscan2
- RNASE9 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 152/406 reads (37%) | SIFT tolerated (0.97); PolyPhen benign (0.018); catalogued as rs770915786, COSV58881188; called by muse, mutect2, varscan2
- RNF112 | c.1833G>A p.M611I | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV71327034; called by muse, mutect2, varscan2
- RORB | c.167C>T p.S56F (on ENST00000396204 / NM_001365023.1; = p.S45F on NM_006914.4) | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65332530, COSV65335980; called by muse, mutect2, varscan2
- ROS1 | c.3404G>A p.G1135E | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142442666; called by muse, mutect2, varscan2
- RPA1 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 108/295 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767278367, COSV54609503, COSV54610564, COSV99628252; called by muse, mutect2, varscan2
- RPSA | c.329A>T p.N110I | Missense Mutation (SNP) | VAF 77/236 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV57192112; called by muse, mutect2, varscan2
- RTL1 | c.2519C>T p.S840F | Missense Mutation (SNP) | VAF 184/440 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1448627892, COSV66016579; called by muse, mutect2, varscan2
- SAMD9L | c.3563G>A p.R1188Q | Missense Mutation (SNP) | VAF 148/379 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs535880866, COSV59080124, COSV59081226; called by muse, mutect2, varscan2
- SCG3 | c.653G>A p.W218* | Nonsense Mutation (SNP) | VAF 141/394 reads (36%) | catalogued as COSV55023218, COSV99590602; called by muse, mutect2, varscan2
- SCML4 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs771489633; called by muse, mutect2, varscan2
- SCN5A | c.5956G>A p.D1986N (on ENST00000333535 / NM_198056.3; = p.D1985N on NM_000335.5) | Missense Mutation (SNP) | VAF 163/458 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs756562718, COSV61115651; called by muse, mutect2, varscan2
- SCN7A | c.2919G>A p.M973I | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as rs1190243173, COSV69271345; called by muse, varscan2
- SCN9A | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 98/277 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.216); catalogued as COSV57619588; called by muse, mutect2, varscan2
- SDK2 | c.3052G>A p.D1018N | Missense Mutation (SNP) | VAF 182/563 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as rs748601515, COSV66181801; called by muse, mutect2, varscan2
- SEC24D | c.3035G>A p.G1012E | Missense Mutation (SNP) | VAF 143/552 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54880764; called by muse, mutect2, varscan2
- SEMG2 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 124/351 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.848); catalogued as COSV65647716; called by muse, mutect2, varscan2
- SERPINA6 | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 193/542 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV58584868; called by muse, mutect2, varscan2
- SERPINB10 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 142/412 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs267605235, COSV53072971; called by muse, varscan2
- SETBP1 | c.3227C>T p.S1076L | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs1449085454, COSV56315771; called by muse, mutect2, varscan2
- SFMBT2 | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 123/332 reads (37%) | catalogued as COSV99055172; called by muse, mutect2, varscan2
- SIPA1L2 | c.3227C>T p.P1076L | Missense Mutation (SNP) | VAF 200/589 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV53398836; called by muse, mutect2, varscan2
- SLC17A1 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 112/439 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs1181244787, COSV55079513; called by muse, mutect2, varscan2
- SLC19A3 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 78/481 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs769023339; called by muse, mutect2, varscan2
- SLC22A14 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.946); catalogued as rs1363064043, COSV99828166; called by muse, mutect2, varscan2
- SLC22A24 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 104/340 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371518525, COSV70301809; called by muse, mutect2
- SLC22A8 | c.1366G>A p.G456R | Missense Mutation (SNP) | VAF 164/418 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs149538913, COSV60324208; called by muse, mutect2, varscan2
- SLC2A4 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 251/612 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV50302748; called by muse, mutect2, varscan2
- SLC38A1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 142/373 reads (38%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as COSV101284146, COSV67064720; called by muse, mutect2, varscan2
- SLC6A11 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 72/232 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as rs1356919073; called by muse, mutect2, varscan2
- SLFN12L | c.1011G>A p.W337* (on ENST00000260908 / NM_001363830.1; = p.W355* on NM_001195790.1) | Nonsense Mutation (SNP) | VAF 67/219 reads (31%) | catalogued as COSV53473535; called by muse, mutect2, varscan2
- SLITRK1 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 124/355 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs749743687, COSV100999776; called by muse, mutect2, varscan2
- SMPD1 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 184/488 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs1162100791; called by muse, mutect2, varscan2
- SNTN | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 147/378 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.563); catalogued as COSV59539609; called by muse, mutect2, varscan2
- SORL1 | c.6579G>A p.G2193= | Splice Region (SNP) | VAF 95/283 reads (34%) | catalogued as rs1395334279; called by muse, mutect2, varscan2
- SP2 | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs776239877; called by muse, mutect2, varscan2
- SPACA1 | c.284T>C p.V95A | Missense Mutation (SNP) | VAF 94/236 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV52759921; called by muse, mutect2, varscan2
- SPAG11B | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 70/510 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); catalogued as rs758891774, COSV52499535; called by muse, mutect2, varscan2
- SPANXD | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 147/198 reads (74%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV65152638; called by muse, mutect2, varscan2
- SPATA31E1 | c.3664C>T p.P1222S | Missense Mutation (SNP) | VAF 184/510 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.043); catalogued as rs1448536018; called by muse, mutect2, varscan2
- SPHKAP | c.2615C>T p.S872F | Missense Mutation (SNP) | VAF 147/422 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV100764437, COSV60893199; called by muse, mutect2, varscan2
- SPIB | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 232/608 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1450263557; called by muse, mutect2, varscan2
- SPOCK2 | c.389G>A p.G130E | Missense Mutation (SNP) | VAF 141/384 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58038905; called by muse, mutect2, varscan2
- SPRR2A | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 100/347 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs770817198; called by muse, mutect2, varscan2
- SSC4D | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 201/472 reads (43%) | catalogued as COSV99300217; called by muse, mutect2, varscan2
- STAG1 | c.3010C>T p.L1004F | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52623539; called by muse, mutect2, varscan2
- STKLD1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 123/326 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs1294670744; called by muse, mutect2, varscan2
- STRC | c.3512G>A p.W1171* | Nonsense Mutation (SNP) | VAF 124/323 reads (38%) | catalogued as COSV68660714; called by muse, mutect2, varscan2
- STXBP5 | c.2549C>T p.T850I (on ENST00000321680 / NM_001127715.2; = p.T814I on NM_139244.4) | Missense Mutation (SNP) | VAF 98/217 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1562269758; called by muse, mutect2, varscan2
- SYBU | c.1024G>A p.E342K (on ENST00000276646 / NM_001099754.2; = p.E341K on NM_017786.6) | Missense Mutation (SNP) | VAF 143/581 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs538401671, COSV52616134; called by muse, mutect2, varscan2
- SYNE2 | c.4688C>T p.S1563L | Missense Mutation (SNP) | VAF 101/294 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as rs748713876, COSV59941406; called by muse, mutect2, varscan2
- SYNJ2 | c.2539C>T p.R847C | Missense Mutation (SNP) | VAF 82/251 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770228724; called by muse, mutect2, varscan2
- TACR3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 327/569 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs778964585, COSV59198545; called by muse, mutect2, varscan2
- TAF1L | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 97/177 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1256765931; called by muse, mutect2, varscan2
- TBC1D5 | c.1252C>T p.P418S | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV53750580; called by muse, mutect2, varscan2
- TBX20 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101282401; called by muse, mutect2, varscan2
- TDRD5 | c.2018A>G p.N673S | Missense Mutation (SNP) | VAF 106/271 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99675538; called by muse, mutect2, varscan2
- TEP1 | c.3866G>A p.R1289Q | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.035); catalogued as rs746588098; called by muse, mutect2, varscan2
- TEP1 | c.2982+1G>A p.X994_splice | Splice Site (SNP) | VAF 103/271 reads (38%) | catalogued as rs1177163590; called by muse, mutect2, varscan2
- TEX15 | c.1103G>A p.G368E (on ENST00000256246; = p.G751E on NM_001350162.2) | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99820982; called by muse, mutect2, varscan2
- TFRC | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.248); catalogued as COSV64054279; called by muse, mutect2, varscan2
- TGFB2 | c.1218G>A p.M406I | Missense Mutation (SNP) | VAF 96/266 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65110682, COSV65111858; called by muse, mutect2, varscan2
- THEMIS | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 160/399 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.209); catalogued as rs1049532553, COSV64069628, COSV64075353; called by muse, mutect2, varscan2
- THSD7A | c.3757C>T p.R1253* | Nonsense Mutation (SNP) | VAF 135/358 reads (38%) | catalogued as rs755356186, COSV69856205; called by muse, mutect2, varscan2
- TMEM33 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs766584485, COSV52562958; called by muse, mutect2, varscan2
- TMPRSS11E | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 196/737 reads (27%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as rs777359481, COSV59520364; called by muse, mutect2, varscan2
- TMPRSS3 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 112/303 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.41); catalogued as rs766015335, COSV52300756, COSV52306513; called by muse, mutect2, varscan2
- TNRC6A | c.2654C>G p.S885C | Missense Mutation (SNP) | VAF 139/376 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777575507; called by mutect2, varscan2
- TNRC6B | c.2761C>T p.R921* | Nonsense Mutation (SNP) | VAF 286/374 reads (76%) | catalogued as COSV57294984; called by muse, mutect2, varscan2
- TNXB | c.3991G>A p.V1331I (on ENST00000647633; = p.V1084I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 315/586 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV64476210; called by muse, mutect2, varscan2
- TPBG | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.503); catalogued as rs866426863, COSV63882240; called by muse, varscan2
- TPM4 | c.114G>A p.Q38= | Splice Region (SNP) | VAF 120/338 reads (36%) | catalogued as rs1324741463, COSV100783738; called by muse, mutect2
- TPTE | c.514G>A p.V172I (on ENST00000618007 / NM_199261.4; = p.V154I on NM_199259.4) | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.156); catalogued as rs773134113; called by muse, mutect2, varscan2
- TPTE2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 95/255 reads (37%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.055); catalogued as COSV55028196, COSV99690802; called by muse, mutect2, varscan2
- TRABD2A | c.1402C>T p.R468C (on ENST00000409520 / NM_001277053.2; = p.R419C on NM_001080824.3) | Missense Mutation (SNP) | VAF 203/527 reads (39%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs770565102, COSV52853835; called by muse, mutect2, varscan2
- TRAPPC11 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 90/326 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100592071; called by muse, mutect2, varscan2
- TRAV26-2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 113/293 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603941; called by muse, mutect2, varscan2
- TRAV27 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 147/373 reads (39%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.7); catalogued as rs1188625843; called by muse, mutect2, varscan2
- TRIM21 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 188/477 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV54344777; called by muse, mutect2, varscan2
- TRIM49B | c.57G>A p.M19I | Missense Mutation (SNP) | VAF 142/376 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.221); catalogued as COSV60321436; called by muse, mutect2, varscan2
- TRIM49C | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 133/362 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.055); catalogued as COSV71510852; called by muse, mutect2, varscan2
- TRIM55 | c.65A>G p.K22R | Missense Mutation (SNP) | VAF 188/600 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.669); catalogued as COSV99396934; called by muse, mutect2, varscan2
- TSPAN7 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 138/177 reads (78%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV54533145; called by muse, mutect2, varscan2
- TTC14 | c.1290+7C>T | Splice Region (SNP) | VAF 70/214 reads (33%) | catalogued as COSV99932123; called by muse, mutect2, varscan2
- TTC21A | c.3391G>A p.G1131S | Missense Mutation (SNP) | VAF 178/486 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs745462293; called by muse, mutect2, varscan2
- TTN | c.28358G>A p.R9453Q (on ENST00000591111; = p.R8526Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 135/399 reads (34%) | PolyPhen possibly damaging (0.67); catalogued as rs368309068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.7711G>A p.E2571K (on ENST00000591111; = p.E2525K on NM_003319.4) | Missense Mutation (SNP) | VAF 151/398 reads (38%) | PolyPhen benign (0.033); catalogued as rs149660690, COSV60136909; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUSC3 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.773); catalogued as COSV101141640, COSV65886777; called by muse, mutect2, varscan2
- UBAP2L | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 182/518 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.135); catalogued as rs745858561; called by muse, mutect2, varscan2
- UNC13A | c.1372G>A p.V458M | Missense Mutation (SNP) | VAF 78/410 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53208040; called by muse, mutect2, varscan2
- UPK3B | c.496C>T p.P166S (on ENST00000257632; = p.P111S on NM_001347684.2) | Missense Mutation (SNP) | VAF 258/978 reads (26%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.226); catalogued as rs1192093267; called by muse, mutect2, varscan2
- URB2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 163/422 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs115399585, COSV50984434, COSV51005769; called by muse, mutect2, varscan2
- USP17L7 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 182/1292 reads (14%) | catalogued as rs1285602004; called by muse, mutect2, varscan2
- USP26 | c.2572G>A p.D858N | Missense Mutation (SNP) | VAF 175/223 reads (78%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1345423915, COSV63707985; called by muse, mutect2, varscan2
- USP54 | c.3892G>A p.E1298K | Missense Mutation (SNP) | VAF 126/353 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.255); catalogued as COSV60440623, COSV60444451; called by muse, mutect2, varscan2
- UTP20 | c.6187C>T p.P2063S | Missense Mutation (SNP) | VAF 187/471 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs1565806049; called by muse, mutect2, varscan2
- VCAN | c.5437C>T p.H1813Y | Missense Mutation (SNP) | VAF 147/418 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99427558; called by muse, mutect2, varscan2
- VPS13B | c.5722C>T p.P1908S | Missense Mutation (SNP) | VAF 130/551 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100663346; called by muse, mutect2, varscan2
- VPS41 | c.1006C>T p.H336Y | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV59651765; called by muse, mutect2, varscan2
- VSTM2A | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 110/328 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56496513; called by muse, mutect2, varscan2
- VWA7 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 151/601 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs1374002768; called by muse, mutect2, varscan2
- WDFY4 | c.3965C>T p.S1322L | Missense Mutation (SNP) | VAF 86/275 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as rs866703278, COSV57433833; called by muse, mutect2, varscan2
- WDR27 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 170/444 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.359); catalogued as rs769998487; called by muse, varscan2
- WDR87 | c.8395C>T p.P2799S | Missense Mutation (SNP) | VAF 161/403 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.967); catalogued as rs762447091, COSV58199629; called by muse, mutect2, varscan2
- WDR87 | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 149/390 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as COSV58206585; called by muse, mutect2, varscan2
- WDR87 | c.3733G>A p.D1245N | Missense Mutation (SNP) | VAF 137/390 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as rs907211965, COSV58194364; called by muse, mutect2, varscan2
- WDR93 | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 123/361 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as rs1235642249, COSV51532423; called by muse, mutect2
- Z83844.2 | c.1426C>T p.P476S | Missense Mutation (SNP) | VAF 168/434 reads (39%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV53216615; called by muse, mutect2, varscan2
- ZBED9 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 146/621 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV71729206; called by muse, mutect2, varscan2
- ZMYM1 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 163/419 reads (39%) | catalogued as rs776794737; called by muse, mutect2, varscan2
- ZNF20 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 52/353 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs752046693; called by muse, mutect2, varscan2
- ZNF233 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 79/401 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs1177765191, COSV100492248; called by muse, mutect2, varscan2
- ZNF34 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV58638747; called by muse, mutect2, varscan2
- ZNF536 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 63/359 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV62821214; called by muse, mutect2, varscan2
- ZNF543 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 126/370 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.101); catalogued as COSV58627178; called by muse, mutect2, varscan2
- ZNF610 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 159/380 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58343578; called by muse, mutect2, varscan2
- ZNF804B | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1036779973; called by muse, mutect2, varscan2
- ZNF836 | c.2147C>T p.P716L | Missense Mutation (SNP) | VAF 143/450 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV59081262, COSV59083544; called by muse, mutect2, varscan2
- ZSCAN10 | c.916C>T p.R306C (on ENST00000252463; = p.R361C on NM_032805.3) | Missense Mutation (SNP) | VAF 195/496 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs777278520; called by muse, mutect2, varscan2
- ZSCAN30 | c.791G>A p.R264K | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99734907; called by muse, mutect2, varscan2
- ABCA4 | c.5345C>T p.S1782F | Missense Mutation (SNP) | VAF 107/356 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC8 | c.4545+1G>A p.X1515_splice | Splice Site (SNP) | VAF 92/262 reads (35%) | called by muse, varscan2
- ABCG8 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 127/353 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- ABR | c.892G>A p.E298K (on ENST00000302538 / NM_021962.5; = p.E261K on NM_001092.5) | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- AC134980.2 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 66/972 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- ADAD2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 257/622 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ADAM30 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 119/354 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- ADAMTS20 | c.5480G>A p.G1827E | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ADAMTS4 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 69/407 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS8 | c.2428A>T p.N810Y | Missense Mutation (SNP) | VAF 157/446 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- ADCY6 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADCY7 | c.1540C>T p.P514S | Missense Mutation (SNP) | VAF 169/446 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ADGRE3 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADGRL3 | c.3782G>A p.G1261E (on ENST00000506720 / NM_001322402.2; = p.G1193E on NM_015236.6) | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL4 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 95/266 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- ADGRV1 | c.12178G>A p.V4060I | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- ADH5 | c.183T>A p.F61L | Missense Mutation (SNP) | VAF 147/588 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- ADORA1 | c.877C>T p.Q293* | Nonsense Mutation (SNP) | VAF 171/465 reads (37%) | called by muse, mutect2, varscan2
- AGBL1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 118/277 reads (43%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- AHCTF1 | c.4862T>C p.F1621S (on ENST00000366508; = p.F1595S on NM_015446.5) | Missense Mutation (SNP) | VAF 124/366 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, varscan2
- ALX4 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 195/494 reads (39%) | called by muse, mutect2, varscan2
- AMER3 | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 125/339 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AMER3 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 282/615 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ANK3 | c.8852G>A p.R2951K | Missense Mutation (SNP) | VAF 140/358 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD11 | c.5240C>T p.P1747L | Missense Mutation (SNP) | VAF 177/503 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ANKRD13A | c.785A>T p.N262I | Missense Mutation (SNP) | VAF 88/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ANKRD30B | c.1864G>A p.G622R | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ANKRD49 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP3B2 | c.2994G>A p.M998I (on ENST00000261722; = p.M992I on NM_004644.5) | Missense Mutation (SNP) | VAF 130/352 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- APOBEC3F | c.476T>A p.F159Y | Missense Mutation (SNP) | VAF 236/327 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- APOBR | c.1877G>A p.G626E (on ENST00000431282; = p.G635E on NM_018690.4) | Missense Mutation (SNP) | VAF 170/478 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGAP28 | c.1599G>A p.W533* (on ENST00000383472 / NM_001366230.1; = p.W374* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 144/431 reads (33%) | called by muse, mutect2
- ARHGAP32 | c.5734C>T p.P1912S (on ENST00000310343 / NM_001378025.1; = p.P1563S on NM_014715.4) | Missense Mutation (SNP) | VAF 189/476 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ARID1A | c.5201A>T p.Y1734F | Missense Mutation (SNP) | VAF 138/363 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ARID2 | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 141/375 reads (38%) | called by muse, mutect2, varscan2
- ASAH2 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 160/405 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ASAP3 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 110/333 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ATG16L1 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 121/352 reads (34%) | called by muse, mutect2, varscan2
- ATP10B | c.3560C>T p.S1187F | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ATRNL1 | c.2239C>T p.L747F | Missense Mutation (SNP) | VAF 89/216 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- B3GALNT2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- BPIFB2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 140/455 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- C11orf95 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 200/594 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, varscan2
- C19orf44 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 119/290 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- C19orf73 | c.322G>A p.V108I | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- C2CD4D | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 247/565 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- C2CD5 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- C8orf89 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 133/454 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CACNA1D | c.1994C>T p.S665F (on ENST00000350061 / NM_001128840.3; = p.S685F on NM_000720.4) | Missense Mutation (SNP) | VAF 164/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAPN14 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 174/488 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CASP10 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 143/386 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CBLIF | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- CCDC168 | c.4367G>A p.R1456K | Missense Mutation (SNP) | VAF 139/331 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CCDC33 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 122/294 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC62 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 116/293 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC68 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 83/243 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- CCM2 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 102/289 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- CCNL2 | c.706C>T p.Q236* | Nonsense Mutation (SNP) | VAF 135/406 reads (33%) | called by muse, mutect2, varscan2
- CCR9 | c.154C>T p.P52S (on ENST00000357632 / NM_031200.3; = p.P40S on NM_006641.4) | Missense Mutation (SNP) | VAF 172/437 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCSER1 | c.2263G>T p.D755Y | Missense Mutation (SNP) | VAF 109/439 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CD1E | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CD300LG | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 192/487 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CD300LG | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 139/360 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CD44 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 150/449 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH17 | c.947A>T p.Y316F | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CDH8 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CEMIP | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 192/477 reads (40%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- CENPL | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 138/407 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CEP135 | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CEP290 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 100/260 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CEP350 | c.3734C>T p.S1245L | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- CFAP54 | c.2447C>T p.T816I | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CFAP54 | c.9171G>A p.E3057= | Splice Region (SNP) | VAF 82/211 reads (39%) | called by muse, mutect2, varscan2
- CFAP57 | c.3427G>A p.E1143K (on ENST00000372492 / NM_001378189.1; = p.E1176K on NM_001195831.3) | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CFH | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 105/308 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFTR | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 266/365 reads (73%) | SIFT tolerated (0.29); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- CILP2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 166/469 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLASRP | c.518C>T p.A173V | Missense Mutation (SNP) | VAF 128/384 reads (33%) | SIFT tolerated (0.16); called by muse, mutect2, varscan2
- CLCF1 | c.334C>T p.H112Y | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CLDN8 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 129/363 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLEC19A | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 190/448 reads (42%) | called by muse, mutect2
- CLEC3A | c.427G>A p.D143N (on ENST00000651443; = p.D134N on NM_005752.6) | Missense Mutation (SNP) | VAF 159/442 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLHC1 | c.692T>C p.L231S | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CLIP4 | c.1526T>C p.F509S | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLYBL | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTN1 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 106/317 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- CNTNAP4 | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 110/321 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNTNAP5 | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTRL | c.3545C>T p.P1182L | Missense Mutation (SNP) | VAF 139/410 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL10A1 | c.1157G>A p.G386E | Missense Mutation (SNP) | VAF 116/314 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL11A2 | c.1786G>A p.E596K (on ENST00000341947 / NM_080680.3; = p.E489K on NM_080679.2) | Missense Mutation (SNP) | VAF 128/884 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COL13A1 | c.1112G>A p.G371E (on ENST00000398978 / NM_001130103.2; = p.G314E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/425 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL18A1 | c.2623T>A p.S875T (on ENST00000359759 / NM_130444.3; = p.S640T on NM_030582.4) | Missense Mutation (SNP) | VAF 166/429 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- COL6A3 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- COL6A6 | c.5143C>T p.P1715S | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- COLQ | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 159/408 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CPA6 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPED1 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 211/278 reads (76%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- CPNE5 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 182/353 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CRB1 | c.2989G>A p.E997K | Missense Mutation (SNP) | VAF 95/247 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- CRLF1 | c.206C>G p.A69G | Missense Mutation (SNP) | VAF 179/527 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, varscan2
- CRMP1 | c.443T>A p.V148D | Missense Mutation (SNP) | VAF 145/378 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- CROCC | c.2443C>T p.Q815* | Nonsense Mutation (SNP) | VAF 171/444 reads (39%) | called by muse, mutect2, varscan2
- CROCC2 | c.4102G>A p.D1368N | Missense Mutation (SNP) | VAF 216/533 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CSF3R | c.1448G>A p.G483E | Missense Mutation (SNP) | VAF 133/381 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSN2 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 191/690 reads (28%) | called by muse, mutect2, varscan2
- CTNNA2 | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 147/429 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTRB2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 101/376 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTNBP2 | c.2857G>A p.V953I | Missense Mutation (SNP) | VAF 172/456 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CUBN | c.5596C>T p.P1866S | Missense Mutation (SNP) | VAF 62/399 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CWC22 | c.1571C>T p.S524F | Missense Mutation (SNP) | VAF 97/248 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CYP19A1 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP4A11 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- CYP4F11 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DCLK1 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- DCT | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- DDR1 | c.2686C>T p.P896S (on ENST00000324771; = p.P859S on NM_001954.4) | Missense Mutation (SNP) | VAF 216/803 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX6 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 157/472 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDX60L | c.1031T>C p.L344S | Missense Mutation (SNP) | VAF 148/287 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- DEPDC5 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 229/332 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DNAH10 | c.3418G>A p.E1140K (on ENST00000409039; = p.E1079K on NM_207437.3) | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DNAH17 | c.10193G>A p.G3398D | Missense Mutation (SNP) | VAF 103/366 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH5 | c.11838G>T p.L3946F | Missense Mutation (SNP) | VAF 109/295 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- DNAH5 | c.5521G>A p.D1841N | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- DNAH7 | c.8557G>A p.E2853K | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DNAH7 | c.7462A>T p.K2488* | Nonsense Mutation (SNP) | VAF 104/301 reads (35%) | called by muse, mutect2, varscan2
- DNAJB7 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 136/367 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DNAJC28 | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 157/417 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DNHD1 | c.12991G>T p.E4331* | Nonsense Mutation (SNP) | VAF 58/354 reads (16%) | called by muse, mutect2, varscan2
- DNM3 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK1 | c.4853C>T p.P1618L | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DOCK5 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- DOP1A | c.2152A>G p.T718A | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPP10 | c.189T>A p.N63K | Missense Mutation (SNP) | VAF 88/259 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DPPA4 | c.542A>T p.N181I | Missense Mutation (SNP) | VAF 173/473 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- DPY19L1 | c.1140T>G p.S380R | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DPYD | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRD1 | c.1325G>A p.G442D | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- DSPP | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 126/429 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- DST | c.15746T>A p.V5249D (on ENST00000361203 / NM_001374722.1; = p.V2837D on NM_015548.5) | Missense Mutation (SNP) | VAF 135/368 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- DST | c.15745G>A p.V5249I (on ENST00000361203 / NM_001374722.1; = p.V2837I on NM_015548.5) | Missense Mutation (SNP) | VAF 157/425 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2
- DUSP16 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 146/375 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EGF | c.1713G>A p.W571* | Nonsense Mutation (SNP) | VAF 92/396 reads (23%) | called by muse, mutect2, varscan2
- EHF | c.407-1G>A p.X136_splice | Splice Site (SNP) | VAF 92/251 reads (37%) | called by muse, mutect2, varscan2
- EIF5 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 115/566 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, varscan2
- EMCN | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 227/407 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML5 | c.1239G>C p.E413D | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- EML5 | c.956T>A p.I319N | Missense Mutation (SNP) | VAF 157/462 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- EPHB3 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 107/487 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- ERAP2 | c.1534G>A p.G512R | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- F3 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- F3 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM171A1 | c.1058G>A p.R353K | Missense Mutation (SNP) | VAF 143/427 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM193A | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 152/416 reads (37%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- FBN2 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 157/431 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- FBN3 | c.1018A>C p.N340H | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- FBP2 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 170/495 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- FCN3 | c.491G>A p.G164E | Missense Mutation (SNP) | VAF 89/252 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FER | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 130/392 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FHAD1 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 183/517 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- FHAD1 | c.4163G>A p.R1388K | Missense Mutation (SNP) | VAF 125/338 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FHL3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- FIGNL1 | c.680A>G p.E227G | Missense Mutation (SNP) | VAF 114/365 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- FILIP1 | c.3096G>A p.M1032I | Missense Mutation (SNP) | VAF 142/367 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG2 | c.4177G>A p.G1393R | Missense Mutation (SNP) | VAF 73/410 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FLNC | c.6629C>T p.S2210F | Missense Mutation (SNP) | VAF 620/781 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- FN1 | c.2440C>T p.P814S | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FRY | c.4289T>C p.V1430A | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- FSIP2 | c.19397C>T p.P6466L | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- FUBP3 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 193/546 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUT3 | c.599G>A p.W200* | Nonsense Mutation (SNP) | VAF 243/597 reads (41%) | called by muse, mutect2, varscan2
- GABRD | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GDF15 | c.883C>A p.Q295K | Missense Mutation (SNP) | VAF 88/235 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- GDPD4 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 94/296 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); called by muse, varscan2
- GIMAP1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 177/503 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); called by muse, mutect2, varscan2
- GIMAP1-GIMAP5 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 206/273 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- GIMAP8 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 336/406 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGA4 | c.*34T>C | Splice Region (SNP) | VAF 138/367 reads (38%) | called by muse, mutect2, varscan2
- GOLGA7B | c.499C>G p.R167G | Missense Mutation (SNP) | VAF 131/397 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GPR52 | c.701C>T p.T234I | Missense Mutation (SNP) | VAF 141/416 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- GPRASP2 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 208/259 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- GRHL1 | c.977C>A p.S326Y | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIN2B | c.3545G>A p.G1182E | Missense Mutation (SNP) | VAF 187/525 reads (36%) | SIFT tolerated (0.93); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRIN3A | c.2359C>T p.H787Y | Missense Mutation (SNP) | VAF 103/269 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- GRIP1 | c.1717C>T p.H573Y (on ENST00000359742 / NM_001379345.1; = p.H521Y on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- GRN | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 169/510 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HAGH | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 45/190 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- HCFC1 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 252/338 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- HCRTR2 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 109/235 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- HHLA1 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 81/363 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HK3 | c.928A>G p.I310V | Missense Mutation (SNP) | VAF 126/314 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HOXC11 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 164/491 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- HPS5 | c.3082G>A p.E1028K (on ENST00000349215 / NM_181507.2; = p.E914K on NM_007216.4) | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HUNK | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HYAL4 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 83/338 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- HYDIN | c.5396C>T p.T1799I | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.272); called by muse, varscan2
- IFT140 | c.3284C>T p.S1095F | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- IGDCC3 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 191/442 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGF2R | c.4085C>T p.P1362L | Missense Mutation (SNP) | VAF 147/402 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- IGHG2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 118/642 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHG4 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 154/688 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHM | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 194/536 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- IGKV1D-8 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLV2-33 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 151/395 reads (38%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF1 | c.3659G>A p.G1220D | Missense Mutation (SNP) | VAF 130/191 reads (68%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGSF1 | c.2000C>T p.A667V | Missense Mutation (SNP) | VAF 205/273 reads (75%) | SIFT tolerated (0.14); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- IGSF10 | c.2173A>G p.T725A | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF10 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 119/349 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL1RL2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL31RA | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 135/417 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ING3 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 197/245 reads (80%) | SIFT tolerated (0.28); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- IPO7 | c.902A>C p.Q301P | Missense Mutation (SNP) | VAF 77/227 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ISM1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 103/531 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITGAL | c.3231T>G p.V1077= | Splice Region (SNP) | VAF 114/292 reads (39%) | called by muse, varscan2
- JCAD | c.3197G>A p.G1066E | Missense Mutation (SNP) | VAF 167/411 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- JHY | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 162/419 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KAAG1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 149/596 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KANK4 | c.1445G>A p.G482E | Missense Mutation (SNP) | VAF 157/410 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- KATNAL2 | c.637C>T p.P213S (on ENST00000356157 / NM_001353899.1; = p.P141S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- KCNA1 | c.789T>G p.I263M | Missense Mutation (SNP) | VAF 148/404 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.09); called by muse, mutect2
- KCNN1 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 230/614 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- KCP | c.4493G>T p.R1498L (on ENST00000620378; = p.R1622L on NM_001366122.1) | Missense Mutation (SNP) | VAF 50/663 reads (8%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); called by muse, mutect2
- KIAA0319L | c.2287C>T p.H763Y | Missense Mutation (SNP) | VAF 150/400 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KIF4B | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 152/439 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR3DL1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- KLC1 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 72/214 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KLHL24 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 117/346 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KLHL29 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 97/574 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- KRT20 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 164/503 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP1-5 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 231/647 reads (36%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMC3 | c.3266C>T p.A1089V | Missense Mutation (SNP) | VAF 162/398 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, varscan2
- LARS1 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 106/279 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LDB2 | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LILRA5 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 274/699 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- LPAR1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPP | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 145/367 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- LRBA | c.6337C>T p.P2113S | Missense Mutation (SNP) | VAF 74/328 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG1 | c.2177G>A p.W726* | Nonsense Mutation (SNP) | VAF 190/507 reads (37%) | called by muse, mutect2, varscan2
- LRRC18 | c.756A>T p.E252D | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC6 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LRRN2 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 195/512 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, varscan2
- LTBP3 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 157/404 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- LZTS2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 107/266 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, varscan2
- MAB21L2 | c.922A>C p.I308L | Missense Mutation (SNP) | VAF 80/602 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- MACF1 | c.21767C>T p.T7256I (on ENST00000372915; = p.T5301I on NM_012090.5) | Missense Mutation (SNP) | VAF 87/248 reads (35%) | called by muse, mutect2, varscan2
- MAGEC1 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 216/292 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MALRD1 | c.850T>A p.S284T | Missense Mutation (SNP) | VAF 175/406 reads (43%) | SIFT tolerated (0.86); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MALRD1 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 175/412 reads (42%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- MALRD1 | c.6227C>T p.T2076I | Missense Mutation (SNP) | VAF 88/254 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MAN1C1 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 208/546 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K4 | c.2596C>T p.P866S | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- MAPK1IP1L | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 190/496 reads (38%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAPT | c.739G>A p.G247R (on ENST00000262410 / NM_001377265.1; = p.G172R on NM_016835.4) | Missense Mutation (SNP) | VAF 279/715 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- MARCHF6 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 53/277 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MARCOL | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 102/291 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- MARK2 | c.320T>C p.L107S | Missense Mutation (SNP) | VAF 60/337 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCC | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 162/514 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MCOLN2 | c.940C>T p.L314F | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MCTP1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 154/408 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, varscan2
- MCTP2 | c.1052A>T p.N351I | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MDGA2 | c.2438G>A p.R813K (on ENST00000399232 / NM_001113498.2; = p.R515K on NM_182830.4) | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MECOM | c.1937G>A p.R646K (on ENST00000468789 / NM_001105078.4; = p.R834K on NM_004991.4) | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- MEX3C | c.1235C>T p.T412I | Missense Mutation (SNP) | VAF 142/415 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MGAM2 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 88/400 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGAM2 | c.4498C>T p.L1500F | Missense Mutation (SNP) | VAF 45/410 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MGAM2 | c.5443C>T p.P1815S | Missense Mutation (SNP) | VAF 320/406 reads (79%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MGAM2 | c.7375G>A p.V2459I | Missense Mutation (SNP) | VAF 121/480 reads (25%) | SIFT deleterious, low confidence (0.02); called by muse, varscan2
- MIDEAS | c.1978C>T p.L660F | Missense Mutation (SNP) | VAF 223/510 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MISP | c.626G>A p.G209E | Missense Mutation (SNP) | VAF 167/488 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MMP14 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 177/420 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MORC1 | c.456A>C p.R152S | Missense Mutation (SNP) | VAF 54/269 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MTG1 | c.403del p.R135Afs*52 | Frame Shift Del (DEL) | VAF 141/473 reads (30%) | called by mutect2, pindel, varscan2
- MUC17 | c.11791G>A p.E3931K | Missense Mutation (SNP) | VAF 88/475 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MUC3A | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 238/315 reads (76%) | SIFT tolerated, low confidence (0.46); called by muse, mutect2, varscan2
- MXRA5 | c.6532A>C p.I2178L | Missense Mutation (SNP) | VAF 180/226 reads (80%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MYH15 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 114/330 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- MYO5C | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 121/299 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAF1 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 196/341 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- NANOS1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 221/572 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2, varscan2
704 further variants in this file (191 protein-altering or splice-affecting, 463 silent, 50 other) are not listed here.
